Somatic mutation profile of tumor specimen 0DEK1J from CCDI case PBBRAB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 12.0 years (4,391 days).
Specimen 0DEK1J: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cbcdb119-0fce-439b-843c-0eb8d9dfc832.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DEJZM (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4801b477-eb29-48b1-9b76-fa79739c1717

The open-access MAF lists 28 somatic variants for this specimen: 16 protein-altering or splice-affecting, 7 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 7, Intron 4, Nonsense Mutation 1, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 391/416 reads (94%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADARB1 | c.2065C>G p.R689G (on ENST00000360697 / NM_001346687.2; = p.R649G on NM_001112.4) | Missense Mutation (SNP) | VAF 32/820 reads (4%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.454); catalogued as COSV62345289; called by muse, mutect2
- FAT4 | c.6382G>A p.D2128N | Missense Mutation (SNP) | VAF 232/552 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV58682891; called by muse, mutect2, varscan2
- KCNK6 | c.691C>T p.R231W | Missense Mutation (SNP) | VAF 241/517 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs553235571, COSV54580065; called by muse, mutect2, varscan2
- LPA | c.2786-1G>T p.X929_splice | Splice Site (SNP) | VAF 174/356 reads (49%) | catalogued as rs201878758; called by muse, mutect2, varscan2
- MCF2 | c.674A>G p.Q225R | Missense Mutation (SNP) | VAF 163/490 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as rs1241153718, COSV58479354; called by muse, mutect2, varscan2
- PRAMEF27 | c.748G>A p.V250I | Missense Mutation (SNP) | VAF 138/325 reads (42%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs1212922517; called by muse, mutect2, varscan2
- RPS6KA4 | c.1189G>A p.A397T | Missense Mutation (SNP) | VAF 119/341 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.371); catalogued as rs1360811119, COSV99589812; called by muse, mutect2, varscan2
- SLX4 | c.1930G>A p.D644N | Missense Mutation (SNP) | VAF 144/313 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs368699362; called by muse, mutect2, varscan2
- SPTBN1 | c.7027G>A p.G2343S | Missense Mutation (SNP) | VAF 478/1050 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.058); catalogued as rs374335221; called by muse, mutect2, varscan2
- ACD | c.1115C>T p.S372L (on ENST00000620338; = p.S283L on NM_022914.3) | Missense Mutation (SNP) | VAF 100/277 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- HDAC2 | c.553G>T p.E185* | Nonsense Mutation (SNP) | VAF 320/741 reads (43%) | called by mutect2, varscan2
- PARP14 | c.2911G>T p.A971S | Missense Mutation (SNP) | VAF 299/689 reads (43%) | SIFT tolerated (0.62); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- PRKCE | c.1903G>C p.V635L | Missense Mutation (SNP) | VAF 215/481 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- PROM1 | c.62G>A p.G21E | Missense Mutation (SNP) | VAF 354/781 reads (45%) | SIFT tolerated (0.59); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- TRRAP | c.4507T>A p.S1503T | Missense Mutation (SNP) | VAF 430/716 reads (60%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.481); called by muse, mutect2, varscan2
- AIFM3 | c.1656C>T p.G552= | Silent (SNP) | VAF 114/300 reads (38%) | catalogued as rs1169802945; called by muse, varscan2
- CADM3 | c.825C>A p.P275= (on ENST00000368125 / NM_001127173.3; = p.P309= on NM_021189.5) | Silent (SNP) | VAF 270/557 reads (48%) | called by muse, mutect2, varscan2
- MAN2A2 | c.2493C>T p.P831= | Silent (SNP) | VAF 199/457 reads (44%) | catalogued as rs373836101; called by muse, mutect2, varscan2
- MMP11 | c.477C>T p.F159= | Silent (SNP) | VAF 20/652 reads (3%) | catalogued as rs141262231; called by muse, mutect2
- NRG3 | c.1569G>A p.T523= | Silent (SNP) | VAF 266/278 reads (96%) | catalogued as rs201130477, COSV64547215; called by muse, mutect2, varscan2
- RITA1 | c.252C>T p.P84= | Silent (SNP) | VAF 303/596 reads (51%) | called by muse, mutect2, varscan2
- TMPRSS13 | c.1062G>A p.T354= | Silent (SNP) | VAF 165/418 reads (39%) | catalogued as rs137959737; called by muse, mutect2, varscan2
- BRD9 | c.1043-49G>A | Intron (SNP) | VAF 6/23 reads (26%) | catalogued as rs763178357; called by mutect2, varscan2
- CASK | c.831+19G>C | Intron (SNP) | VAF 146/382 reads (38%) | called by muse, mutect2, varscan2
- CCNL2 | c.660-547C>T | Intron (SNP) | VAF 207/398 reads (52%) | catalogued as rs1364294294; called by muse, mutect2, varscan2
- RAB30 | c.361+96G>C | Intron (SNP) | VAF 27/65 reads (42%) | called by muse, mutect2, varscan2
- ZNF467 | chr7:149778011 G>T | 5'Flank (SNP) | VAF 230/711 reads (32%) | called by muse, mutect2, varscan2
